CCDI case PBCAIP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3a4c5198-3312-4d57-907e-ca69cd5fbcc1

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Pineoblastoma: ICD-O-3 morphology code: 9362/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.1 years (1,874 days).

Biospecimens (4 samples)
- Sample 0DMIO1: Tissue type: Tumor; Specimen type: Solid Tissue.
- Samples 0DMIOI, 0DMZ6G (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DMIPI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
